Somatic mutation profile of tumor specimen TARGET-40-NAAHDL-01A (aliquot TARGET-40-NAAHDL-01A-01D) from TARGET case TARGET-40-NAAHDL, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Bones of skull and face and associated joints; Age at diagnosis: 14.1 years (5,167 days).
Specimen TARGET-40-NAAHDL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c195f2e3-bec8-4f85-b0d2-4ba4d86ac9b8.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAHDL-10A (Blood Derived Normal), aliquot TARGET-40-NAAHDL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/112739be-6c92-4349-aa77-bec2320654ef

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 20/54 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763098116, CM078491, COSV52693726, COSV52826087, COSV53107923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNGA3 | c.396C>T p.S132= | Splice Region (SNP) | VAF 35/116 reads (30%) | catalogued as rs1174225295, COSV55621819; called by muse, mutect2, varscan2
- TCHH | c.4270A>C p.S1424R | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as rs867777633; called by muse, mutect2
- GOLGB1 | c.7863G>T p.L2621F | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
